Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4962, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4962-01A (Primary Tumor).

[page 1 of 2]
TCGA-BP-4962

SURGICAL PATHOLOGY REPORT

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

Left renal mass

Specimens Submitted:

1: Kidney, left lower pole, heminephrectomy

DIAGNOSIS:

1. Kidney, left lower pole, heminephrectomy:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 8.5 cm.

Local Invasion (for renal cortical types):

Extends through renal capsule but confined within Gerota's fascia

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT2 Tumor >7.0 cm in greatest dimension limited to the kidney

Comment: The tumor cells are positive for CD10, Vimentin, EMA and focally for E-cadherin, supporting the diagnosis.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
Special Studies:

Result	Special Stain	Comment
	CD10	
	VIMEN	
	EMA	
	E-CADHERIN	
	NEG CONT	
	IMM RECUT	

Gross Description:

1). The specimen is received fresh and is labeled "left lower pole hemi-nephrectomy" and consists of a partial nephrectomy specimen weighing 937 g and measuring 20.0 x 15.0 x 7.5 cm with attached fat. The portion of kidney measures 8.5 x 6.0 x 4.5 cm with no gross tumor apparent at the superior cauterized surgical margin. On cut section of variegated yellow and focally hemorrhagic mass identified measuring 8.5 x 5.4 x 4.5 cm. The mass grossly invades to the capsule and into the surrounding perinephric fat, but does not extend beyond Gerota's fascia. The tumor comes to within 0.6 cm of the parenchymal margin and 1.5 cm of the inked external fat. The adjacent uninvolved renal parenchyma is tan-brown and no gross abnormalities. No renal pelvis is identified. The specimen is photographed and a portion of tumor is submitted for TPS. Representative sections are submitted.

Summary of sections:

TC-tumor invading capsule and extending into perinephric fat.

TP-tumor with deep parenchymal margin

TN-tumor with normal kidney parenchyma

F-inked external fat

Summary of Sections:**Part 1: Kidney, left lower pole, heminephrectomy**

Block	Sect. Site	PCs
2	f	2
2	tc	2
3	tn	3
3	tp	3

Source: NCI Genomic Data Commons file d8e7ffe9-a1c5-4b5c-b114-cbc54d838a42 (TCGA-BP-4962.678C3778-77B4-4E59-AF83-1CFC3BB9CBD3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).